Gene-level copy-number profile of tumor specimen C3L-08169-01 from CPTAC case C3L-08169, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G4; Age at diagnosis: 64.8 years (23,663 days).
Specimen C3L-08169-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b9970bdb-32bd-42c8-84aa-e6d06679a4fb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08169-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,257 have no estimate.
https://portal.gdc.cancer.gov/files/5bdc3e38-5ce6-4ce4-9fbe-c2cd8e156dc1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 1,066; copy number 2: 46,111; copy number 3: 6,780; copy number 4: 4,104; copy number 5: 91; copy number 6: 91; copy number 7: 15; copy number 8: 23; copy number 9: 8; copy number 10: 8; copy number 11: 19; copy number 12: 7; copy number 13: 5; copy number 23: 8; copy number 32: 2; copy number 33: 4.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,426,263–212,426,360, 1 gene (within-gene range 0–1): MIR548F2.
- chr2:217,799,588–218,033,982, 3 genes: TNS1, MIR6809, TNS1-AS1.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr11:5,663,195–5,938,619, 1 gene (within-gene range 0–2): TRIM5.
- chr11:5,736,448–5,904,448, 13 genes (within-gene range 0–2): OR56B1, OR52N4, OR56B2P, OR52N5, OR52N1, OR52N3P, OR52N2, OR52E6, OR52E8, OR52E7P, OR52E4, OR52E5, OR52Q1P.
- chr12:17,383,352–17,400,914, 2 genes: PSMC1P8, TIMM17BP1.
- chr15:47,133,495–47,134,122, 1 gene: AC066615.1.
- chr16:61,743,154–61,743,476, 1 gene (within-gene range 0–2): RN7SKP76.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 235 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:36,968,383–37,084,372, 1 gene, copy number 5: HEATR5B.
- chr2:88,931,666–90,154,574, 65 genes, copy number 5–11 (within-gene range 2–11) (broad region; genes not listed).
- chr2:90,172,802–91,781,169, 22 genes, copy number 6–32: IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P.
- chr2:159,670,708–159,771,027, 3 genes, copy number 5 (within-gene range 3–5): AC009961.1, RPS3AP13, MARCHF7.
- chr3:90,202,316–90,261,708, 2 genes, copy number 5: PROS2P, HSPE1P19.
- chr3:153,129,074–153,170,627, 3 genes, copy number 7: AC117394.1, AC117394.2, RAP2B.
- chr7:62,275,361–62,275,678, 1 gene, copy number 6: AC128676.1.
- chr8:85,440,596–85,464,915, 1 gene, copy number 5 (within-gene range 2–5): CA3-AS1.
- chr8:86,180,418–86,212,236, 1 gene, copy number 5: AC084128.1.
- chr8:143,603,210–143,656,418, 4 genes, copy number 5 (within-gene range 2–5): PYCR3, GFUS, AC067930.2, ZNF623.
- chr8:143,734,139–143,815,773, 3 genes, copy number 7 (within-gene range 3–7): IQANK1, AC105219.3, SCRIB.
- chr9:67,697,076–68,644,442, 23 genes, copy number 6–11 (within-gene range 3–11): Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1, RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506.
- chr10:38,762,095–42,185,791, 4 genes, copy number 6–7: AL133173.1, AL590623.1, KSR1P1, IGKV1OR10-1.
- chr10:42,242,721–42,281,819, 2 genes, copy number 6: AL031601.2, PABPC1P8.
- chr11:787,115–867,116, 13 genes, copy number 5: CEND1, SLC25A22, AP006621.6, PIDD1, RPLP2, SNORA52, PNPLA2, AP006621.1, CRACR2B, CD151, POLR2L, TSPAN4, AP006623.1.
- chr11:54,591,480–54,592,409, 1 gene, copy number 10: OR4C50P.
- chr11:90,085,950–90,118,461, 3 genes, copy number 5: UBTFL1, AP000648.2, AP000648.1.
- chr13:89,402,398–89,818,453, 2 genes, copy number 6 (within-gene range 3–6): LINC02336, LINC01040.
- chr14:18,333,726–18,602,129, 9 genes, copy number 13–33: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12.
- chr16:46,469,341–46,831,180, 15 genes, copy number 6: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87.
- chr18:65,186,159–65,187,018, 1 gene, copy number 6: AC007631.1.
- chr19:1,852,382–1,926,013, 8 genes, copy number 5: AC012615.3, KLF16, AC012615.4, AC012615.1, AC012615.5, ABHD17A, SCAMP4, ADAT3.
- chr21:8,603,547–13,120,807, 48 genes, copy number 6–23: RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 1,065. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
